Somatic mutation profile of tumor specimen C3L-01054-04 (aliquot CPT0123990009) from CPTAC case C3L-01054, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 38.4 years (14,036 days).
Specimen C3L-01054-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7308e26b-adf9-483b-a295-d948631dc645.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01054-31 (Blood Derived Normal), aliquot CPT0124920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60dd7f66-b0f3-4379-a497-ff69acad6fd9

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 2, Splice Site 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP5F1B | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1259301376; called by muse, mutect2
- CR2 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 16/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100889492; called by muse, mutect2
- EPB41L1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99150106; called by muse, mutect2
- FLNC | c.7087G>C p.D2363H | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100368390; called by muse, mutect2
- FYB1 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV60942015; called by muse, mutect2
- IRF3 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1049794743; called by muse, mutect2, varscan2
- OR14A16 | c.80T>A p.I27N | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV62926150; called by muse, mutect2
- RELN | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58992959; called by muse, mutect2
- SLX4 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369805557; called by muse, mutect2
- TFAP2C | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); catalogued as rs1568753299, COSV52371122; called by muse, mutect2
- TGFBR2 | c.968T>G p.L323R | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55444207; called by muse, mutect2
- AC092143.1 | c.1318+2_1318+30del p.X440_splice | Splice Site (DEL) | VAF 32/340 reads (9%) | called by mutect2, pindel
- CHRM5 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.323); called by muse, mutect2
- DENND1C | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- FAM169A | c.232+1G>A p.X78_splice | Splice Site (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- GRIK2 | c.1962C>A p.N654K | Missense Mutation (SNP) | VAF 21/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LEPROT | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2
- NDUFS1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCH1 | c.2491A>T p.S831C (on ENST00000340059 / NM_001130960.2; = p.S843C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMG2 | c.804C>A p.H268Q | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); called by muse, mutect2
- UPB1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CLIC5 | c.768C>T p.T256= (on ENST00000185206 / NM_001370649.1; = p.T97= on NM_016929.5) | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV51763029; called by muse, mutect2
- UQCC1 | c.45T>G p.S15= | Silent (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2
- PITX2 | c.185-965C>T | Intron (SNP) | VAF 13/368 reads (4%) | called by muse, mutect2
- TBCE | c.1302+21C>A | Intron (SNP) | VAF 39/333 reads (12%) | called by muse, mutect2, varscan2
